Gene-level copy-number profile of tumor specimen ALCH-AE0J-TTP1-A from ALCHEMIST case ALCH-AE0J, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 73.4 years (26,817 days).
Specimen ALCH-AE0J-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 655602bd-0cca-4f43-a136-f7553b191103.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE0J-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/11658c9e-88d3-449e-8406-4db4932e2b21

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 3,137; copy number 2: 55,472; copy number 3: 279; copy number 4: 7; copy number 5: 1; copy number 7: 4; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:40,481,558–40,642,117, 6 genes: AQP7P5, FP885919.1, AMYH02020865.1, BMS1P14, FP325318.1, IGKV1OR9-2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:135,802,985–135,803,075, 1 gene, copy number 8: MIR5692C1.
- chr9:40,223,285–40,293,955, 4 genes, copy number 7: ANKRD20A2P, RNU6-1269P, BX664727.2, SNX18P8.
- chr10:133,420,666–133,424,572, 1 gene, copy number 5 (within-gene range 2–5): SPRN.

Autosomal genes at a single copy (total copy number 1): 301. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
